Surgical pathology report (de-identified scan), TCGA case TCGA-FG-7638, project TCGA-LGG (Brain Lower Grade Glioma), tissue source site Case Western, specimen TCGA-FG-7638-01B (Primary Tumor).

[page 1 of 5]
Clinical History:	Left frontal craniotomy with resection of lesion
Pre-Operative Diagnoses:	None Given
Post-Operative Diagnosis:	None Given
Specimen(s) Submitted:	A. Left frontal tumor; B. Left frontal lesion; C. Posterior margin frontal tumor
CPT Code(s)	88307 X 3; 88333 X 3; 88342 X 1

FINAL DIAGNOSIS:

- A. Left frontal tumor: Anaplastic oligodendroglioma. See note.
- B. Left frontal tumor: Anaplastic oligodendroglioma (70% of tissue).. See note.
- C. Posterior margin, frontal tumor: Anaplastic oligodendroglioma (50% of tissue). See note.

Note: While some portions of the tumor retain a moderately cellular, monotonous population of round glial cells with a delicate capillary pattern, other areas are highly cellular, with increased nuclear pleomorphism, and scattered mitoses. Tumor cells infiltrate into cortex and show perineuronal satellitosis. The tumor corresponds to a WHO grade III. Chromosome studies will be sent, and the results reported as an addendum.

BRAIN: Resection

MACROSCOPIC

Specimen Type

X Resection

Specimen Size

Greatest dimensions: A: 1 x 0.7 x 0.4 cm. B: 4.8 x 3.8 x 1 cm aggregate C: is a 3.8 x 3 x 1.2 cm aggregate

Technical Performing Location:

For questions regarding this case:

[page 2 of 5]
NEUROPATHOLOGY REPORT *****Addendum*****

Pathology #:

Tumor Site

☒ Cerebrum: left frontal

Tumor Size

☒ Cannot be determined

MICROSCOPIC

Histologic Type

☒ Anaplastic oligodendroglioma

Histologic Grade

☒ WHO Grade III

Margins

☒ Cannot be assessed

*Additional Studies

* ☒ Molecular testing: 1p 19 q

Frozen Section Diagnosis:

- A. Left frontal mass ()
- Infiltrating glioma (grade 2 or 3, possibly oligodendroglioma).
()
- B. Left frontal mass ()
- No tumor seen.
()
- C. Frontal tumor, posterior margin ()
- Positive for glioma.

Gross Description:

This case has 3 parts, each received fresh.

- A. Labeled "left frontal tumor" is a 1 x 0.7 x 0.4 cm piece of irregular gray-tan soft tissue. The specimen is step-sectioned and entirely submitted in cassette A1.

[page 3 of 5]
NEUROPATHOLOGY REPORT *****Addendum*****

Pathology #:

- B. Labeled "left frontal tumor" is a 4.8 x 3.8 x 1 cm aggregate of multiple pieces of irregular gray-tan tissue consistent with brain tissue. No discrete lesion is grossly identified. Representative sections are submitted in cassettes B1-B6.
- C. Labeled "posterior margin frontal tumor" is a 3.8 x 3 x 1.2 cm aggregate of multiple pieces of irregular gray-tan apparent brain tissue without a discrete lesion grossly identified. The specimen is step-sectioned and entirely submitted in cassettes C1-C6.

Microscopic Description:

I have reviewed all diagnostic slides and have edited the gross and/or microscopic portion of this report as part of my pathologic assessment and final diagnosis.

The pathologist signing this report is located at .

[page 4 of 5]
NEUROPATHOLOGY REPORT *****Addendum*****

Pathology #:

Immunostain for the astrocytic marker p53 is negative, supporting the above diagnosis.

Pathologist

[page 5 of 5]
NEUROPATHOLOGY REPORT ***Addendum*******

Pathology #:

Chromosome studies performed by FISH on paraffin blocks of tumor ([REDACTED]), report [REDACTED]) showed the following:

Chromosome 1p loss.
Chromosome 19q loss.

Pathologist

Source: NCI Genomic Data Commons file dfe5e30c-662b-41e3-a96c-5afbad21764a (TCGA-FG-7638.2A94AFDC-2504-4B73-8B1E-C9BE3183654D.PDF), Data Release 46.0 - August 10, 2026; text from the OCR (chandra-v1.5.0).